Somatic mutation profile of tumor specimen TCGA-IB-7645-01A (aliquot TCGA-IB-7645-01A-22D-2201-08) from TCGA case TCGA-IB-7645, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 44.2 years (16,126 days).
Specimen TCGA-IB-7645-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fd4bbca-9f16-4ebc-97a0-f08cba83a8c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-7645-10A (Blood Derived Normal), aliquot TCGA-IB-7645-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e79f14e6-0b30-4c4a-9cc3-04e194a200ee

The open-access MAF lists 29 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 19, Silent 6, Nonsense Mutation 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 14/155 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 27/304 reads (9%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2
- ADCYAP1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 32/876 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99327561; called by muse, mutect2
- APOB | c.5831A>G p.H1944R | Missense Mutation (SNP) | VAF 34/872 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1558564719, COSV51936849; called by muse, mutect2
- CFAP65 | c.2281G>A p.A761T | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.055); catalogued as COSV100445415; called by muse, mutect2
- CR1 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs1318306169, COSV100887784; called by muse, mutect2
- GRIK5 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 42/566 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as rs766656809, COSV53482804; called by muse, mutect2
- GSDMC | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 36/680 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.041); catalogued as rs754298748, COSV52693400; called by muse, mutect2
- KCNA6 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 12/407 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54975264; called by muse, mutect2
- KRT40 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 72/705 reads (10%) | catalogued as COSV100898868; called by muse, mutect2, varscan2
- LRRC43 | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 25/485 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV99928274; called by muse, mutect2
- MYO16 | c.2816A>G p.N939S | Missense Mutation (SNP) | VAF 60/508 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.264); catalogued as COSV99194146; called by muse, mutect2, varscan2
- NDST3 | c.2270T>C p.V757A | Missense Mutation (SNP) | VAF 23/357 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV99631086; called by muse, mutect2
- NTM | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 50/803 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.418); catalogued as rs763797870, COSV100868239, COSV100868975; called by muse, mutect2
- OR2T10 | c.777C>G p.Y259* | Nonsense Mutation (SNP) | VAF 24/318 reads (8%) | catalogued as COSV100393749; called by muse, mutect2
- PBRM1 | c.1819-1G>A p.X607_splice | Splice Site (SNP) | VAF 24/308 reads (8%) | catalogued as COSV56259114; called by muse, mutect2
- PKD1L1 | c.1790C>T p.T597M | Missense Mutation (SNP) | VAF 13/377 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs1266263317, COSV99220503; called by muse, mutect2
- PKHD1L1 | c.5161C>A p.L1721I | Missense Mutation (SNP) | VAF 146/1141 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.334); catalogued as COSV101006514; called by muse, mutect2, varscan2
- REG3A | c.455G>A p.S152N | Missense Mutation (SNP) | VAF 28/713 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100532801; called by muse, mutect2
- RS1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 43/666 reads (6%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.024); catalogued as rs146477940, COSV101183831; ClinVar: benign; called by muse, mutect2
- TRPV6 | c.2232G>T p.R744S | Missense Mutation (SNP) | VAF 33/496 reads (7%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.381); catalogued as COSV100844357, COSV63890800; called by muse, mutect2
- UGGT2 | c.1757A>G p.H586R | Missense Mutation (SNP) | VAF 109/753 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as COSV100948768; called by muse, mutect2, varscan2
- TMEM131 | c.1536G>T p.M512I | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DYRK2 | c.651C>T p.H217= (on ENST00000344096 / NM_006482.3; = p.H144= on NM_003583.4) | Silent (SNP) | VAF 16/270 reads (6%) | catalogued as rs1409963245, COSV59847590; called by muse, mutect2
- IZUMO2 | c.279G>A p.T93= | Silent (SNP) | VAF 32/369 reads (9%) | catalogued as rs1392862887, COSV99518316; called by muse, mutect2
- KIAA1109 | c.5391G>A p.K1797= | Silent (SNP) | VAF 13/426 reads (3%) | catalogued as COSV52695213, COSV99166872; called by muse, mutect2
- KPRP | c.624C>T p.F208= | Silent (SNP) | VAF 64/1084 reads (6%) | catalogued as rs764225483, COSV100908736, COSV64221008; called by muse, mutect2
- OR4Q3 | c.687C>T p.I229= | Silent (SNP) | VAF 19/506 reads (4%) | catalogued as COSV59177386; called by muse, mutect2
- SVOPL | c.501G>A p.T167= (on ENST00000419765; = p.T15= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/715 reads (11%) | catalogued as rs371993600; called by mutect2, varscan2
